Somatic mutation profile of tumor specimen SM-JU32N (aliquot 7316UP-287) from CPTAC case C224106, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Parietal lobe; Tumor grade: G4.
Specimen SM-JU32N: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8be9bc58-a565-42e3-9511-1c344ccd0069.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105215 (Blood Derived Normal), aliquot 7316UP-287-1105215; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eefcfcb9-2797-4963-9eb0-d63aa46129c2

The open-access MAF lists 50 somatic variants for this specimen: 32 protein-altering or splice-affecting, 14 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 14, Intron 3, In Frame Del 2, Nonsense Mutation 1, RNA 1, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASB12 | c.862G>A p.V288I | Missense Mutation (SNP) | VAF 78/101 reads (77%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs748815216, COSV62857329; called by muse, mutect2, varscan2
- BTBD11 | c.967G>A p.A323T | Missense Mutation (SNP) | VAF 34/175 reads (19%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.007); catalogued as rs1398296978; called by muse, mutect2, varscan2
- CDH18 | c.2184C>A p.S728R | Missense Mutation (SNP) | VAF 149/390 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.841); catalogued as COSV56924162, COSV99935390; called by muse, mutect2, varscan2
- CXCR3 | c.1054C>T p.R352C | Missense Mutation (SNP) | VAF 51/68 reads (75%) | SIFT deleterious (0); PolyPhen benign (0.23); catalogued as rs373077208; called by muse, mutect2, varscan2
- GDPD4 | c.1501_1504del p.F501Kfs*16 (on ENST00000376217; = p.F501Kfs*21 on NM_182833.3) | Frame Shift Del (DEL) | VAF 18/101 reads (18%) | catalogued as rs774497362; called by mutect2, pindel, varscan2
- GTF3C5 | c.890G>T p.R297L | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV59599657; called by muse, mutect2, varscan2
- HRNR | c.575G>A p.R192H | Missense Mutation (SNP) | VAF 189/417 reads (45%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs148184849; called by muse, mutect2, varscan2
- LAMB1 | c.3037C>T p.R1013W | Missense Mutation (SNP) | VAF 163/579 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs767303427; called by muse, mutect2, varscan2
- LIPJ | c.302C>T p.T101M | Missense Mutation (SNP) | VAF 99/149 reads (66%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.841); catalogued as rs781183196; called by muse, mutect2, varscan2
- NCBP1 | c.2341G>A p.V781M | Missense Mutation (SNP) | VAF 117/247 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs377264051; called by muse, mutect2, varscan2
- OR10W1 | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 53/127 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.219); catalogued as rs200070425, COSV67720621; called by muse, mutect2, varscan2
- OR52N1 | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 173/404 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs146336745; called by muse, mutect2, varscan2
- RAB44 | c.35G>A p.R12Q | Missense Mutation (SNP) | VAF 129/314 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1432024122; called by muse, mutect2, varscan2
- RASGRP2 | c.1577G>A p.G526D | Missense Mutation (SNP) | VAF 150/437 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100818304, COSV62450841; called by muse, mutect2, varscan2
- SAMSN1 | c.524C>T p.T175M | Missense Mutation (SNP) | VAF 134/310 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs756805588, COSV53478979; called by muse, mutect2, varscan2
- SMIM17 | c.80G>A p.R27Q | Missense Mutation (SNP) | VAF 92/250 reads (37%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as rs184713147; called by muse, mutect2, varscan2
- TRIM58 | c.284G>C p.R95P | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.482); catalogued as rs1011119348; called by muse, mutect2, varscan2
- TRIML1 | c.736-1G>A p.X246_splice | Splice Site (SNP) | VAF 62/194 reads (32%) | catalogued as COSV60195163; called by muse, mutect2, varscan2
- C16orf96 | c.1846C>A p.P616T | Missense Mutation (SNP) | VAF 112/296 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- CYB5R4 | c.1294G>A p.D432N | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.491); called by muse, mutect2
- EDRF1 | c.716_719delinsG p.D239_S240delinsG | In Frame Del (DEL) | VAF 74/138 reads (54%) | called by pindel, varscan2*
- ENOSF1 | c.76G>A p.D26N | Missense Mutation (SNP) | VAF 578/846 reads (68%) | SIFT deleterious, low confidence (0); called by muse, varscan2
- FAM91A1 | c.1652T>G p.L551W | Missense Mutation (SNP) | VAF 56/163 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FER1L5 | c.127G>T p.V43L | Missense Mutation (SNP) | VAF 48/162 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- HJURP | c.1963G>A p.A655T | Missense Mutation (SNP) | VAF 78/174 reads (45%) | SIFT tolerated (0.85); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ITSN2 | c.3655C>T p.Q1219* | Nonsense Mutation (SNP) | VAF 73/169 reads (43%) | called by muse, mutect2, varscan2
- KRT18 | c.1204A>C p.M402L | Missense Mutation (SNP) | VAF 203/523 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- LAMA1 | c.8509T>C p.Y2837H | Missense Mutation (SNP) | VAF 318/394 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LMBRD1 | c.908_910del p.K303del (on ENST00000649011; = p.K281del on NM_018368.4) | In Frame Del (DEL) | VAF 120/365 reads (33%) | called by pindel, varscan2
- MGAM2 | c.4924G>A p.G1642R | Missense Mutation (SNP) | VAF 41/164 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- MRPL39 | c.628A>T p.I210F | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.381); called by muse, mutect2
- UTP20 | c.5422G>A p.V1808I | Missense Mutation (SNP) | VAF 51/138 reads (37%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- AKT1S1 | c.6G>A p.A2= (on ENST00000344175 / NM_001098633.4; = p.A22= on NM_032375.5) | Silent (SNP) | VAF 91/214 reads (43%) | catalogued as rs757867938; called by muse, mutect2, varscan2
- ARHGAP35 | c.1203G>T p.R401= | Silent (SNP) | VAF 16/188 reads (9%) | called by muse, mutect2
- ARID1B | c.6639G>A p.S2213= | Silent (SNP) | VAF 6/11 reads (55%) | catalogued as rs1319153432, COSV51648257; called by muse, mutect2, varscan2
- C3 | c.3744T>C p.F1248= | Silent (SNP) | VAF 32/435 reads (7%) | catalogued as rs147441936; called by muse, mutect2
- CD74 | c.138C>T p.R46= | Silent (SNP) | VAF 49/125 reads (39%) | catalogued as rs376043210; called by muse, mutect2, varscan2
- CSNK1D | c.861G>T p.V287= | Silent (SNP) | VAF 168/453 reads (37%) | called by muse, mutect2, varscan2
- FAM98C | c.933C>T p.N311= | Silent (SNP) | VAF 69/217 reads (32%) | catalogued as rs745545912, COSV53038483; called by muse, mutect2, varscan2
- KCNK6 | c.789C>T p.H263= | Silent (SNP) | VAF 178/460 reads (39%) | catalogued as rs200538663; called by muse, mutect2, varscan2
- LPAR3 | c.465C>T p.I155= | Silent (SNP) | VAF 125/293 reads (43%) | catalogued as rs565409119, COSV65452543; called by muse, mutect2, varscan2
- MGAT4D | c.750G>A p.K250= | Silent (SNP) | VAF 36/81 reads (44%) | called by muse, mutect2, varscan2
- NAV3 | c.2247G>A p.P749= | Silent (SNP) | VAF 100/261 reads (38%) | catalogued as rs367740483; called by muse, mutect2, varscan2
- OR2L5 | c.270T>C p.S90= | Silent (SNP) | VAF 138/329 reads (42%) | called by muse, mutect2, varscan2
- SCN2B | c.348C>T p.N116= | Silent (SNP) | VAF 277/701 reads (40%) | catalogued as rs72544144; ClinVar: likely benign; called by muse, mutect2, varscan2
- SCRN1 | c.1161G>T p.L387= | Silent (SNP) | VAF 78/328 reads (24%) | called by muse, mutect2, varscan2
- ARPP19P2 | n.290A>G | RNA (SNP) | VAF 57/142 reads (40%) | catalogued as rs1320789244; called by muse, mutect2, varscan2
- ENTPD5 | c.218-185G>A | Intron (SNP) | VAF 83/195 reads (43%) | called by muse, mutect2, varscan2
- KCNQ5 | c.616+1022C>T | Intron (SNP) | VAF 12/37 reads (32%) | catalogued as rs145744729, COSV59660159; called by muse, mutect2, varscan2
- NXN | c.361-37938C>T | Intron (SNP) | VAF 155/387 reads (40%) | catalogued as rs74436197; called by muse, mutect2, varscan2
